Gene-level copy-number profile of tumor specimen TCGA-CN-4741-01A from TCGA case TCGA-CN-4741, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Gum, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 75.3 years (27,506 days).
Specimen TCGA-CN-4741-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.33b2d42e-b1d4-4c49-aade-675b386c0f4b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CN-4741-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b7420106-50b8-410e-b7af-4ed2ef939b85

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 38; copy number 2: 3,687; copy number 3: 703; copy number 4: 50,534; copy number 6: 2,970; copy number 9: 35; copy number 11: 4; copy number 12: 1,027; copy number 13: 36; copy number 16: 775.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CN-4741-01A-01D-1432-01): tumor purity 0.64, ploidy 4.29, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,877 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:91,356,755–198,222,513, 1,802 genes, copy number 12–16 (broad region; genes not listed).
- chr11:76,349,956–79,612,300, 71 genes, copy number 9–13 (broad region; genes not listed).
- chr19:45,001,449–45,076,587, 4 genes, copy number 11 (within-gene range 4–11): RELB, CLASRP, RNU6-611P, ZNF296.

Autosomal genes at a single copy (total copy number 1): 38. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
